Somatic mutation profile of tumor specimen 0DI3LY from CCDI case PBBURD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 15.4 years (5,609 days).
Specimen 0DI3LY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 660be895-4bc9-4ccf-a72f-dcc8fffcb698.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI3JA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffabd3b7-0c44-4fcd-8b19-0803f533d4d9

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Intron 4, Frame Shift Ins 3, Nonsense Mutation 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 564/1302 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by mutect2, varscan2
- CEACAM20 | c.343C>A p.Q115K | Missense Mutation (SNP) | VAF 415/830 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.083); catalogued as rs777438412; called by muse, mutect2, varscan2
- CEP97 | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 516/1176 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs773873294, COSV59124545; called by muse, mutect2, varscan2
- FAM120B | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 868/2033 reads (43%) | catalogued as rs771547946, COSV99380054; called by muse, mutect2, varscan2
- FBXO31 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 74/1448 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs775309853, COSV61148613; called by muse, mutect2
- GRID2 | c.2869G>A p.V957M | Missense Mutation (SNP) | VAF 582/1292 reads (45%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as rs763070360; called by muse, mutect2, varscan2
- IQUB | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 88/1500 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs370004563; called by muse, mutect2
- MGAM | c.5002C>T p.R1668C | Missense Mutation (SNP) | VAF 88/1819 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs750406655, COSV72074599; called by muse, mutect2
- MYOM2 | c.2132C>T p.P711L | Missense Mutation (SNP) | VAF 40/905 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750124935; called by muse, mutect2
- PTCH1 | c.2776T>C p.W926R | Missense Mutation (SNP) | VAF 1298/1361 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM032346; called by muse, mutect2, varscan2
- SHROOM2 | c.4467del p.M1490Cfs*10 | Frame Shift Del (DEL) | VAF 42/289 reads (15%) | catalogued as COSV66604612; called by mutect2, pindel, varscan2
- VPS35L | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 569/1268 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV51990893; called by muse, mutect2, varscan2
- CKS2 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 63/924 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2
- KLRB1 | c.373A>G p.K125E | Missense Mutation (SNP) | VAF 535/1196 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- LHX1 | c.313dup p.Y105Lfs*7 | Frame Shift Ins (INS) | VAF 1073/1570 reads (68%) | called by mutect2, pindel, varscan2
- OR13C3 | c.1032dup p.P345Tfs*? | Frame Shift Ins (INS) | VAF 314/1044 reads (30%) | called by mutect2, pindel, varscan2
- SF3B3 | c.1701G>T p.E567D | Missense Mutation (SNP) | VAF 510/1135 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SHROOM2 | c.3426_3427insT p.A1143Cfs*50 | Frame Shift Ins (INS) | VAF 68/556 reads (12%) | called by mutect2, varscan2*
- CDSN | c.660G>A p.S220= | Silent (SNP) | VAF 545/1204 reads (45%) | catalogued as rs780616557, COSV52538025; called by muse, mutect2, varscan2
- EMX2 | c.45G>A p.L15= | Silent (SNP) | VAF 60/869 reads (7%) | called by muse, mutect2
- FREM2 | c.3738G>A p.T1246= | Silent (SNP) | VAF 136/1551 reads (9%) | catalogued as rs530142447, COSV54844222; ClinVar: uncertain significance; called by muse, mutect2
- PKDREJ | c.5991G>A p.V1997= | Silent (SNP) | VAF 850/1891 reads (45%) | called by muse, mutect2, varscan2
- RNF146 | c.21A>G p.E7= (on ENST00000368314 / NM_001242850.2; = p.E6= on NM_030963.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 48/1102 reads (4%) | called by muse, mutect2
- C1orf131 | c.693+72G>A | Intron (SNP) | VAF 55/644 reads (9%) | catalogued as rs773444729; called by muse, mutect2
- CACNA1D | c.5040+48G>C | Intron (SNP) | VAF 337/754 reads (45%) | called by muse, mutect2, varscan2
- CPSF7 | c.-56+10del | Intron (DEL) | VAF 51/137 reads (37%) | called by mutect2, pindel, varscan2
- DNPEP | c.775-27G>A | Intron (SNP) | VAF 108/232 reads (47%) | called by muse, mutect2, varscan2
- ZC3H3 | c.*91G>A | 3'UTR (SNP) | VAF 30/479 reads (6%) | catalogued as rs995170387; called by muse, mutect2
